Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-4859, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-4859-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

Accession Number: [REDACTED] Report Status: Amend/Addenda
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

CASE: [REDACTED]
PATIENT: [REDACTED]

Resident: [REDACTED]
Pathologist: [REDACTED]

CGA-CZ-4859

PATHOLOGIC DIAGNOSIS:

✓RIGHT KIDNEY, NEPHRECTOMY (including FSA):
RENAL CELL CARCINOMA, (5.0 cm) clear cell type, Fuhrman grade 2 (of 4).
Tumor is confined to the kidney.
No LVI is identified.
Vascular and ureteric margins of resection are negative for tumor.

AJCC Classification (6th Edition): T1 N0 MX.

Special stains to assess adjacent uninvolved renal parenchyma will be performed and results will be issued as an addendum.

CLINICAL DATA:

History: Not provided.
Operation: Hand assisted laparoscopic right nephrectomy.✓
Clinical Diagnosis: Right renal mass.

TISSUE SUBMITTED:

A/1. Right kidney - Frozen section.

O.R. CONSULTATION:

SPECIMEN LABELED "#1. RIGHT KIDNEY" (FSA):
Renal cell carcinoma.

OR Consultation by: [REDACTED]

Resident: [REDACTED]

The senior physician certifies that he/she personally conducted a gross and/or microscopic examination of the described specimen(s) and rendered or confirmed the rapid diagnos(es) related thereto.

GROSS DESCRIPTION:

The specimen is received fresh, labeled with the patient's name, unit number, and "#1. Right kidney", and consists of a 313.5 gm right kidney that measures 11.0 x 6.5 x 4.3 cm with a ureter (8.8 x 0.3 cm), stapled renal vein (2.1 x 1.2 cm), and renal artery (3.5 x 0.3 cm). The specimen is inked and bivalved to reveal a 5.0 x 4.3 x 2.5 cm a well-circumscribed tan/yellow, focally cystic mass that is approximately 9.0 cm to ureter, 2.0 cm to the vein, and 1.8 cm to the renal artery. The tumor does not grossly appear to involve the renal vein. Tumor appears confined to the kidney. Representative section of the tumor is submitted as FSA. In addition, a representative section is sent for Cytogenetics, EM, and tissue banking. A representative section of the normal kidney is sent for EM, IF, and tissue banking.

Micro A1: FSA remnant, 1 frag, [REDACTED]
Micro A2: Vascular and ureteral margins, 3 frags, [REDACTED]
Micro A3: Contents of cassette labeled "T1" (received along with FSA remnant), 2 frags, [REDACTED]
Micro A4: Tumor capsule and perirenal fat, 1 frag, [REDACTED]
Micro A5: Additional tumor with respect to renal capsule, 2 frags, [REDACTED]
Micro A6: Tumor and adjacent normal kidney, 1 frag, [REDACTED]
Micro A7: Normal kidney, 1 frag, [REDACTED]

By his/her signature below, the senior physician certifies that he/she

[page 2 of 3]
[REDACTED]

Pathology Report

personally conducted a microscopic examination ("gross only" exam, if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

Resident Review by [REDACTED]

Final Diagnosis by [REDACTED]

ADDENDUM

RENAL PATHOLOGY EVALUATION OF NON-NEOPLASTIC KIDNEY PARENCHYMA [REDACTED]:

RIGHT KIDNEY, NEPHRECTOMY:

MINIMAL CHRONIC CHANGES OF THE KIDNEY PARENCHYMA, MOST LIKELY AGE-RELATED (SEE NOTE)

NOTE:

The non-neoplastic renal parenchyma sample examined shows minimal chronic changes, within the expected range for a [REDACTED] year-old woman. There is minimal focal global glomerulosclerosis involving 2.0% of glomeruli, minimal tubular atrophy and interstitial fibrosis (less than 10% of the parenchyma), and a mild degree of arterial sclerosis.

The non-neoplastic kidney parenchyma has been reviewed by Dr. [REDACTED]
Renal Pathologist.

MICROSCOPIC DESCRIPTION:

Sections of formalin-fixed, paraffin-embedded tissue (block A7) were evaluated using HE, PAS, Jones silver methenamine, and trichrome (AFOG) stains. The sample consists of cortex and medulla. There are 245 glomeruli present, of which 5 (2.0%) are globally sclerosed. The remaining glomeruli show a very mild expansion of the mesangial areas by extracellular matrix material. The basement membranes show no significant craters or double contours. Rare distal tubules contain PAS-positive hyaline casts. Less than 10% of the cortical parenchyma shows tubular atrophy and interstitial fibrosis. The arteries exhibit mild subintimal sclerosis.

[REDACTED]

[page 3 of 3]
Pathology Report

Accession Number: [REDACTED]

Report Status [REDACTED]

Type: Cytogenetics

CASE: [REDACTED]

PATIENT: [REDACTED]

Cytogeneticist: [REDACTED]

KARYOTYPE: see interpretation

METAPHASES COUNTED: 0

ANALYZED: 0

SCORED: 0

BANDING: GTG

INTERPRETATION:

No metaphases were available from this specimen, therefore the cytogenetic analysis could not be performed.

INDICATION FOR TEST:

? RCC

Source: NCI Genomic Data Commons file 695e7b61-ba92-4890-9e29-acae1519b3c8 (TCGA-CZ-4859.C8B57DA4-A68A-4110-970C-B38479E21AE2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).